Gene-level copy-number profile of tumor specimen TCGA-4Z-AA7Q-01A from TCGA case TCGA-4Z-AA7Q, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 79.3 years (28,981 days).
Specimen TCGA-4Z-AA7Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.3656af31-e3c8-4c22-b1c4-b0bd2e552606.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4Z-AA7Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/061f72f4-9943-4418-8b5b-b74479078403

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 1,261; copy number 2: 20,750; copy number 3: 24,167; copy number 4: 11,997; copy number 5: 617; copy number 6: 363; copy number 7: 395; copy number 8: 20; copy number 9: 19; copy number 11: 22; copy number 12: 20; copy number 19: 84.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4Z-AA7Q-01A-11D-A390-01): tumor purity 0.29, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 102 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,011,910–22,552,156, 102 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 560 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,474,825–43,023,637, 144 genes, copy number 7–19 (within-gene range 4–19) (broad region; genes not listed).
- chr1:147,019,656–151,583,583, 202 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:151,612,038–151,629,430, 2 genes, copy number 7: AL391335.1, RNU6-1062P.
- chr1:153,297,862–153,500,764, 13 genes, copy number 9: PGLYRP3, PGLYRP4, RNU6-160P, S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A, S100A7A, S100A7P1, S100A7L2, S100A7, RN7SL44P.
- chr1:160,670,148–162,599,842, 92 genes, copy number 7 (broad region; genes not listed).
- chr1:167,721,192–171,345,307, 87 genes, copy number 7 (broad region; genes not listed).
- chr2:60,336,446–60,554,467, 6 genes, copy number 9 (within-gene range 4–9): MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1.
- chr3:136,250,340–136,951,606, 14 genes, copy number 8 (within-gene range 4–8): PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.3, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1.

Autosomal genes at a single copy (total copy number 1): 1,237. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
